Somatic mutation profile of tumor specimen TCGA-28-2509-01A (aliquot TCGA-28-2509-01A-01D-1494-08) from TCGA case TCGA-28-2509, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.3 years (28,240 days).
Specimen TCGA-28-2509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac21aa37-79a1-4021-a20e-5ac69bb0b961.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2509-10A (Blood Derived Normal), aliquot TCGA-28-2509-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0493f571-b732-4f33-9c57-b9b5762e7da1

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 64/80 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1428C>G p.N476K (on ENST00000297504 / NM_001282291.2; = p.N459K on NM_007188.5) | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV52507849, COSV52509173, COSV99874722; called by muse, mutect2, varscan2
- ACKR1 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 207/395 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371909350, COSV63672582; called by muse, mutect2, varscan2
- CARMIL2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV58030790; called by muse, mutect2, varscan2
- CNDP1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs750727146, COSV62595005; called by muse, mutect2, varscan2
- DNAH3 | c.3284C>T p.P1095L | Missense Mutation (SNP) | VAF 159/265 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54544608; called by muse, mutect2, varscan2
- ERG | c.821C>T p.T274M (on ENST00000398919 / NM_001243428.1; = p.T250M on NM_004449.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.083); catalogued as rs751217612, COSV55735173; called by muse, mutect2, varscan2
- FAT2 | c.8158G>C p.D2720H | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1053738091, COSV55827370; called by muse, mutect2, varscan2
- FKRP | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.62); PolyPhen benign (0.339); catalogued as rs779317138, COSV59359933; called by muse, mutect2, varscan2
- FOXI1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775317199, COSV60389708; called by muse, mutect2, varscan2
- FRAS1 | c.10840C>G p.L3614V | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53638659; called by muse, mutect2, varscan2
- GCN1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV56113495; called by muse, varscan2
- HCCS | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372501217, COSV58239558; called by muse, mutect2, varscan2
- IGSF1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 70/242 reads (29%) | catalogued as rs1412267674, COSV63839375; called by muse, mutect2, varscan2
- KIT | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as rs766253584, COSV55416803; ClinVar: uncertain significance; called by mutect2, varscan2
- KSR2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs373055394; called by muse, mutect2, varscan2
- LRRK2 | c.62_65del p.V21Gfs*2 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs1431729780; called by mutect2, pindel, varscan2
- MAST1 | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 132/227 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV52250522; called by muse, mutect2, varscan2
- MORF4L2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1391087680, COSV64610661; called by muse, mutect2, varscan2
- NEK3 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV51618733; called by muse, mutect2, varscan2
- OR2A25 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV68716856, COSV68717061; called by muse, mutect2
- OR4A47 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); catalogued as rs750401492, COSV71445108; called by muse, mutect2, varscan2
- OR4C3 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs202136357, COSV60589783; called by muse, mutect2, varscan2
- OR5W2 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV60617989; called by muse, mutect2, varscan2
- OTOGL | c.5206G>A p.D1736N (on ENST00000547103; = p.D1727N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100087338; called by muse, mutect2, varscan2
- PARP9 | c.210C>G p.D70E | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV64451600; called by muse, mutect2, varscan2
- PCDHB7 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781810804, COSV50796991, COSV50808733; called by muse, mutect2, varscan2
- PRAG1 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV58165566; called by muse, mutect2, varscan2
- SAPCD2 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1445757862, COSV68836809; called by muse, mutect2, varscan2
- SEMA7A | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56089294, COSV56092010; called by muse, mutect2, varscan2
- SLIT3 | c.812C>A p.P271Q | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV60628941; called by muse, mutect2, varscan2
- SULT1B1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV60209079; called by muse, mutect2, varscan2
- TJP1 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 51/98 reads (52%) | catalogued as COSV62045360; called by muse, mutect2, varscan2
- USP28 | c.3004G>A p.A1002T | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs994275475, COSV50181012; called by muse, mutect2, varscan2
- VENTX | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1163207878, COSV58085221; called by muse, mutect2, varscan2
- ZNF157 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs774229424, COSV65658963; called by muse, mutect2, varscan2
- ZNF626 | c.605A>T p.K202I | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as COSV74130559; called by muse, mutect2, varscan2
- SP100 | c.1062del p.N355Ifs*6 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- SRCAP | c.7981del p.D2661Mfs*17 | Frame Shift Del (DEL) | VAF 39/82 reads (48%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2516C>T p.T839I | Missense Mutation (SNP) | VAF 154/388 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CATSPERD | c.2079C>T p.I693= | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as rs573139640, COSV58467063; called by muse, mutect2, varscan2
- GALNT3 | c.1533C>T p.S511= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs770800462, COSV67062303; called by muse, mutect2, varscan2
- GANAB | c.639G>A p.E213= | Silent (SNP) | VAF 106/238 reads (45%) | catalogued as rs1212752726, COSV60466789, COSV60467928; called by muse, mutect2, varscan2
- GCC1 | c.1410T>C p.A470= | Silent (SNP) | VAF 133/428 reads (31%) | catalogued as COSV58463547; called by muse, mutect2, varscan2
- GM2A | c.177C>T p.I59= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs745799277, COSV64095848; called by muse, mutect2, varscan2
- INTS6L | c.117C>T p.R39= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs782778650, COSV66085777; called by muse, mutect2
- MAGEB6 | c.669G>A p.K223= | Silent (SNP) | VAF 106/175 reads (61%) | catalogued as COSV66872825; called by muse, mutect2, varscan2
- MID2 | c.234C>T p.T78= | Silent (SNP) | VAF 226/384 reads (59%) | catalogued as COSV53306677, COSV53313001; called by muse, mutect2, varscan2
- MUC16 | c.951C>T p.A317= | Silent (SNP) | VAF 126/242 reads (52%) | catalogued as rs1343902868, COSV67486708; called by muse, mutect2, varscan2
- PTPRB | c.5529C>T p.I1843= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as COSV54250599; called by muse, mutect2, varscan2
- SLC8B1 | c.1596C>T p.G532= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs751541902, COSV52530059; called by muse, mutect2, varscan2
- TSNARE1 | c.432C>T p.H144= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100211491, COSV56181874; called by muse, mutect2, varscan2
- GSG1 | c.481+111G>A | Intron (SNP) | VAF 20/113 reads (18%) | catalogued as COSV100189285; called by muse, mutect2, varscan2
- PDZRN4 | c.844-68492C>T | Intron (SNP) | VAF 199/416 reads (48%) | catalogued as COSV100114626; called by muse, mutect2, varscan2
- SNORD116-23 | n.72G>A | RNA (SNP) | VAF 123/332 reads (37%) | catalogued as rs747068486; called by muse, mutect2, varscan2
